Somatic mutation profile of tumor specimen 0DT9NL from CCDI case PBCIAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Hemangioendothelioma, malignant; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 21.5 years (7,837 days).
Specimen 0DT9NL: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fe4614a-3024-4d7f-ae3d-26d361fa3632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9N8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82b86669-09b7-41e4-92ce-00a5c00a566c

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 35/576 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV99171063; called by muse, mutect2
- RAB5A | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 49/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56085840; called by muse, mutect2
- TRPC7 | c.1283T>G p.I428S | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100725762; called by muse, mutect2
- FNDC3A | c.2661T>A p.D887E (on ENST00000492622 / NM_001079673.2; = p.D831E on NM_014923.5) | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.455); called by muse, mutect2
- KRT77 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SPIDR | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 10/351 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
